TCGA case TCGA-29-1692 — Ovarian Serous Cystadenocarcinoma (TCGA-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary; Tissue source site: Duke. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/92960f76-0242-4a1c-bf7d-014c2f720219

Demographics
Sex at birth: female; Race: white; Age at index: 58 years; Vital status: Dead; Days to death: 2,872 days (7.9 years).

Diagnoses (2)
1. Serous cystadenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8441/3; ICD-10 code: C56.9; Tissue or organ of origin: Ovary; Site of resection or biopsy: Ovary; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 58.0 years (21,193 days); Year of diagnosis: 1997; Method of diagnosis: Surgical Resection; FIGO stage: Stage IIIC; Tumor grade: G2; Prior treatment: No; Residual disease: R1.
   Pathology details: Residual tumor measurement: 11-20 mm.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Treatment intent type: Adjuvant; Days to treatment start: 5 days; Number of cycles: 3; Treatment dose: 7 AUC; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Days to treatment start: 5 days; Number of cycles: 3; Treatment dose: 175 mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin + Paclitaxel; Initial disease status: Recurrent Disease; Days to treatment start: 544 days (1.5 years); Route of administration: Intraperitoneal / Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Pegylated Liposomal Doxorubicin Hydrochloride; Initial disease status: Progressive Disease; Days to treatment start: 1,548 days (4.2 years); Number of cycles: 8; Route of administration: Intravenous.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Tamoxifen; Initial disease status: Progressive Disease; Days to treatment start: 1,793 days (4.9 years); Days to treatment end: 2,125 days (5.8 years); Treatment dose: 20 mg.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin + Docetaxel; Initial disease status: Progressive Disease; Days to treatment start: 2,120 days (5.8 years); Days to treatment end: 2,247 days (6.2 years); Number of cycles: 6; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide; Initial disease status: Progressive Disease; Days to treatment start: 2,278 days (6.2 years); Days to treatment end: 2,521 days (6.9 years); Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Initial disease status: Progressive Disease; Days to treatment start: 2,556 days (7.0 years); Days to treatment end: 2,577 days (7.1 years); Number of cycles: 2; Treatment dose: 289 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Initial disease status: Progressive Disease; Days to treatment start: 2,616 days (7.2 years); Days to treatment end: 2,785 days (7.6 years); Number of cycles: 6; Treatment dose: 45 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine; Initial disease status: Progressive Disease; Days to treatment start: 2,616 days (7.2 years); Days to treatment end: 2,785 days (7.6 years); Number of cycles: 6; Treatment dose: 1,250 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Topotecan; Initial disease status: Progressive Disease; Days to treatment end: 694 days (1.9 years); Route of administration: Intravenous.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Recurrence of diagnosis 1 (Serous cystadenocarcinoma, NOS). Age at diagnosis: 59.5 years (21,737 days); Days to diagnosis: 544 days (1.5 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 2,837 days (7.8 years).
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Radiation Therapy, NOS; Radiation Therapy, NOS, for recurrent disease.

Follow-up (4 entries)
- Day 544 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 544 days (1.5 years).
- Days to follow up: 2,872 days (7.9 years); Disease response: With Tumor.
- Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Timepoint: Post Initial Treatment.
- ECOG performance status: 0; Timepoint: Post Adjuvant Therapy.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-29-1692-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 0.7; Intermediate dimension: 0.5; Shortest dimension: 0.2.
  Slide TCGA-29-1692-01B-01-TS1: Section location: Top; Percent tumor cells: 60; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 40.
  Slide TCGA-29-1692-01B-01-BS1: Section location: Bottom; Percent tumor cells: 70; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 20.
- Sample TCGA-29-1692-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Longest dimension: 1; Intermediate dimension: 0.6; Shortest dimension: 0.6.
  Slide TCGA-29-1692-02A-01-TS1: Section location: Top; Percent tumor cells: 60; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 20; Percent stromal cells: 20.
  Slide TCGA-29-1692-02A-01-BS1: Section location: Bottom; Percent tumor cells: 60; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 20; Percent stromal cells: 20.
- Sample TCGA-29-1692-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Serous Cystadenocarcinoma; Tumor status: With tumor; History neoadjuvant treatment: No; Performance status timing: Post-Adjuvant Therapy; Anatomic organ subdivision: Right; Method initial path diagnosis: Tumor resection.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 2: Therapy regimen: Progression.
- Drug treatment 3, Route of administrations: Route of administration: IP; Route of administration: IV.
- Drug treatment 5: Pharmaceutical therapy drug name: Cytoxan; Therapy regimen: Progression.
- Drug treatment 6: Pharmaceutical therapy drug name: Doxil; Therapy regimen: Progression.
- Drug treatment 11: Pharmaceutical therapy drug name: Taxol.
- Drug treatment 12: Pharmaceutical therapy drug name: Taxotere; Therapy regimen: Progression.
- Follow-up form: Treatment outcome first course: Complete Remission/Response; Tumor status: With tumor; Performance status timing: Post-Adjuvant Therapy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 2,872 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 2,872 days; disease-free interval: event (new tumor event after initially disease-free), 544 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 544 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; sample TCGA-29-1692-01): tumor purity 0.53, ploidy 2.84, whole-genome doublings 1 (call status: snp_call).
